Gene-level copy-number profile of tumor specimen TCGA-DX-AB2E-01A from TCGA case TCGA-DX-AB2E, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 60.6 years (22,117 days).
Specimen TCGA-DX-AB2E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.36591489-6cde-447d-acfe-18fa30b2b005.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78be4af0-abe8-4c83-9772-ef76666a0d5e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 568; copy number 2: 20,539; copy number 3: 26,089; copy number 4: 8,899; copy number 5: 3,315; copy number 6: 213; copy number 7: 40; copy number 8: 28; copy number 10: 4; copy number 11: 14; copy number 16: 29; copy number 17: 68; copy number 19: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2E-01A-11D-A38Y-01): tumor purity 0.51, ploidy 5.15, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:97,916,353–98,049,043, 3 genes: CRYZP2, RPL5P12, DUTP8.
- chr10:66,079,243–66,118,326, 1 gene: AC022017.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 185 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:30,718,805–31,351,725, 6 genes, copy number 8–10: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1.
- chr5:39,371,675–42,191,523, 38 genes, copy number 8–11 (within-gene range 4–11): DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1.
- chr5:42,465,400–42,468,868, 2 genes, copy number 11: SERBP1P6, AC093225.1.
- chr5:43,602,692–44,066,731, 4 genes, copy number 7: NNT, RPL29P12, AC104119.1, RNU6-381P.
- chr8:122,091,480–123,416,350, 35 genes, copy number 7: MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6.
- chr9:5,311,444–7,203,458, 43 genes, copy number 17: HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1.
- chr9:15,422,704–17,797,124, 25 genes, copy number 17: SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:19,108,375–20,995,955, 29 genes, copy number 16 (within-gene range 1–16): PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.
- chr9:25,579,657–25,678,440, 2 genes, copy number 19: AL353730.1, TUSC1.
- chr10:16,823,966–17,129,811, 1 gene, copy number 7 (within-gene range 5–7): CUBN.

Autosomal genes at a single copy (total copy number 1): 568. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
